Somatic mutation profile of tumor specimen TCGA-BP-5170-01A (aliquot TCGA-BP-5170-01A-01D-1429-08) from TCGA case TCGA-BP-5170, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.4 years (20,229 days).
Specimen TCGA-BP-5170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 739fcc5a-b48a-4668-b016-41a82a101540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5170-11A (Solid Tissue Normal), aliquot TCGA-BP-5170-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0c5a2cd-e074-40aa-a1aa-83db7c7e9979

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Del 5, Splice Site 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.341-8_341-2del p.X114_splice | Splice Site (DEL) | VAF 52/213 reads (24%) | hotspot (GDC flag); catalogued as COSV56564202; called by mutect2, pindel, varscan2
- ADAM9 | c.1288T>A p.C430S | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65962920; called by muse, mutect2, varscan2
- APOB | c.12520G>A p.G4174S | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51956197; called by muse, mutect2, varscan2
- CACNA1D | c.6055C>A p.L2019M (on ENST00000350061 / NM_001128840.3; = p.L2039M on NM_000720.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.321); catalogued as COSV55458105, COSV55467443; called by muse, mutect2, varscan2
- CATSPERG | c.2277C>A p.F759L | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV53054674; called by muse, mutect2, varscan2
- CD300LG | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53226215; called by muse, mutect2, varscan2
- CD300LG | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53226231; called by muse, mutect2, varscan2
- CD74 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 113/502 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV50535251; called by muse, mutect2, varscan2
- CLSPN | c.262A>T p.N88Y | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV52057918; called by muse, mutect2, varscan2
- CXorf21 | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66763448; called by muse, mutect2, varscan2
- DCAF13 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV52574961; called by muse, mutect2, varscan2
- DCTD | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1488036260, COSV63867386; called by muse, mutect2, varscan2
- FOXP2 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV63495183; called by muse, mutect2, varscan2
- LAMA1 | c.5758G>T p.A1920S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV67545288; called by muse, mutect2, varscan2
- MOXD1 | c.1258A>G p.N420D | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as COSV60950073; called by muse, mutect2, varscan2
- PARP4 | c.4303C>A p.P1435T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV67964678, COSV67965000; called by muse, mutect2, varscan2
- PAX1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as rs202103929, COSV68273661; ClinVar: likely benign; called by muse, mutect2, varscan2
- PBRM1 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 58/245 reads (24%) | catalogued as COSV56308731; called by muse, mutect2, varscan2
- PLAAT3 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV60313015; called by muse, mutect2, varscan2
- PRR16 | c.383G>T p.R128M (on ENST00000407149 / NM_001300783.2; = p.R105M on NM_016644.2) | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65407268; called by muse, mutect2, varscan2
- RPS2 | c.380T>A p.F127Y | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV51911452; called by muse, mutect2, varscan2
- RREB1 | c.3061T>A p.S1021T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as COSV58567031; called by muse, mutect2, varscan2
- SCG2 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 107/480 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV59542067; called by muse, mutect2, varscan2
- TSPAN1 | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs184135661; called by muse, mutect2, varscan2
- TWNK | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 62/301 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52972698; called by muse, mutect2, varscan2
- USP24 | c.5229G>A p.M1743I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs1199473782, COSV53780293; called by muse, mutect2, varscan2
- ZFP3 | c.805A>C p.I269L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV59584400; called by muse, mutect2, varscan2
- ERP44 | c.124del p.I42Ffs*2 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- IL12RB2 | c.1804_1813del p.T602Vfs*50 | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | called by mutect2, pindel, varscan2
- KMT2A | c.6485_6492delinsA p.L2162* | Frame Shift Del (DEL) | VAF 25/192 reads (13%) | called by pindel, varscan2*
- SMG8 | c.2836_2840del p.L946Tfs*2 | Frame Shift Del (DEL) | VAF 39/176 reads (22%) | called by mutect2, pindel, varscan2
- STK31 | c.1692del p.E565Sfs*4 | Frame Shift Del (DEL) | VAF 87/569 reads (15%) | called by mutect2, pindel, varscan2
- ABCD3 | c.1018T>C p.L340= | Silent (SNP) | VAF 63/265 reads (24%) | catalogued as COSV64644865; called by muse, mutect2, varscan2
- CDK6 | c.672T>C p.D224= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV56014323; called by muse, mutect2, varscan2
- CEP164 | c.2820C>T p.A940= | Silent (SNP) | VAF 91/323 reads (28%) | catalogued as COSV54047232; called by muse, mutect2, varscan2
- PIK3R4 | c.759A>G p.T253= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as rs1376252283, COSV63244389; called by muse, mutect2, varscan2
- RANBP2 | c.7155A>G p.R2385= | Silent (SNP) | VAF 220/895 reads (25%) | catalogued as COSV51709820; called by muse, mutect2, varscan2
- RNF145 | c.574T>C p.L192= (on ENST00000424310 / NM_001199383.2; = p.L220= on NM_144726.2) | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs779622416, COSV50875075; called by muse, mutect2, varscan2
- SLC6A12 | c.177C>G p.V59= | Silent (SNP) | VAF 54/256 reads (21%) | catalogued as COSV62886422; called by muse, mutect2, varscan2
- SNW1 | c.252T>C p.N84= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as COSV55057394; called by muse, mutect2, varscan2
- TBC1D19 | c.1156T>C p.L386= | Silent (SNP) | VAF 103/397 reads (26%) | catalogued as COSV53522537; called by muse, mutect2, varscan2
- UIMC1 | c.2074T>C p.L692= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as COSV65895368; called by muse, mutect2, varscan2
